Somatic mutation profile of tumor specimen TCGA-MX-A663-01A (aliquot TCGA-MX-A663-01A-11D-A31L-08) from TCGA case TCGA-MX-A663, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Stomach, NOS; AJCC pathologic stage: Stage IIA; Tumor grade: G3; Age at diagnosis: 66.9 years (24,421 days).
Specimen TCGA-MX-A663-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c16c3e5c-369d-4ebd-9ac0-e907decea397.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-MX-A663-10A (Blood Derived Normal), aliquot TCGA-MX-A663-10A-01D-A31J-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/91fc2e74-3a43-4762-bc73-fd9b671fdd8b

The open-access MAF lists 80 somatic variants for this specimen: 68 protein-altering or splice-affecting, 12 silent.
By variant classification: Missense Mutation 59, Silent 12, Nonsense Mutation 6, Frame Shift Del 1, In Frame Del 1, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.148C>T p.Q50* | Nonsense Mutation (SNP) | VAF 116/314 reads (37%) | hotspot (GDC flag); catalogued as rs864622636, CM023895, COSV58683786; ClinVar: pathogenic; called by muse, mutect2, varscan2
- DSP | c.1520C>T p.S507F | Missense Mutation (SNP) | VAF 22/145 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1240326550, CM088034, COSV101131256; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- TIMM50 | c.446C>T p.T149M | Missense Mutation (SNP) | VAF 17/101 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1244226820, COSV100067902; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ACBD5 | c.1468C>T p.Q490* (on ENST00000375888 / NM_001352568.1; = p.Q481* on NM_145698.5 and 4 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 21/114 reads (18%) | catalogued as COSV101022538; called by muse, mutect2, varscan2
- ACHE | c.1481G>A p.R494Q | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT tolerated (0.1); PolyPhen benign (0.057); catalogued as rs374462106; called by muse, mutect2, varscan2
- ACSM2A | c.1316G>T p.G439V (on ENST00000219054; = p.G360V on NM_001308169.2) | Missense Mutation (SNP) | VAF 35/176 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.333); catalogued as COSV99525177; called by muse, mutect2, varscan2
- ACTRT2 | c.22G>C p.D8H | Missense Mutation (SNP) | VAF 4/64 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.798); catalogued as COSV101007598; called by muse, mutect2
- ANKRD11 | c.2446G>A p.E816K | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.125); catalogued as rs1183047246, COSV56355432; called by muse, mutect2, varscan2
- CHD7 | c.3735G>C p.M1245I | Missense Mutation (SNP) | VAF 4/99 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101418205; called by muse, mutect2
- CNTLN | c.3379_3381del p.E1127del | In Frame Del (DEL) | VAF 9/63 reads (14%) | catalogued as rs766864864; called by pindel, varscan2
- DNAH7 | c.9599G>A p.R3200H | Missense Mutation (SNP) | VAF 7/96 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1435352362, COSV100414949, COSV56768429; called by muse, mutect2
- DSC2 | c.2162C>T p.T721M | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.416); catalogued as rs759513934, COSV51865903; called by muse, mutect2, varscan2
- ECSIT | c.1073C>G p.A358G | Missense Mutation (SNP) | VAF 17/97 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99368996; called by muse, mutect2, varscan2
- EPHX1 | c.413G>A p.G138D | Missense Mutation (SNP) | VAF 10/284 reads (4%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.905); catalogued as COSV99688904; called by muse, mutect2
- GPR45 | c.364G>A p.V122M | Missense Mutation (SNP) | VAF 48/120 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as COSV99306912; called by muse, mutect2, varscan2
- GSE1 | c.2293G>A p.E765K | Missense Mutation (SNP) | VAF 9/85 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs753550740, COSV99496444; called by muse, mutect2, varscan2
- HKDC1 | c.394G>A p.D132N | Missense Mutation (SNP) | VAF 20/91 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV100664526; called by muse, mutect2, varscan2
- HTR1A | c.862G>A p.A288T | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT tolerated (0.77); PolyPhen benign (0.018); catalogued as rs1260684033, COSV60499881; called by muse, mutect2, varscan2
- JMJD1C | c.4165A>G p.N1389D | Missense Mutation (SNP) | VAF 14/179 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.021); catalogued as COSV100550470; called by muse, mutect2
- KIF21B | c.2800G>T p.V934F | Missense Mutation (SNP) | VAF 12/69 reads (17%) | SIFT tolerated (0.6); PolyPhen benign (0.049); catalogued as COSV59753390; called by muse, mutect2, varscan2
- KIF4B | c.2182C>T p.R728W | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as rs776866601, COSV70528828; called by muse, mutect2, varscan2
- KLF3 | c.308C>T p.P103L | Missense Mutation (SNP) | VAF 17/108 reads (16%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.446); catalogued as COSV54710542; called by muse, mutect2, varscan2
- LIN7A | c.217C>A p.H73N | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.522); catalogued as COSV99692032; called by muse, mutect2, varscan2
- LMBRD1 | c.1223G>A p.R408Q (on ENST00000649011; = p.R386Q on NM_018368.4) | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as rs772350306, COSV65296128; called by muse, mutect2, varscan2
- LPAR5 | c.68G>A p.R23H | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as rs368795459; called by muse, mutect2, varscan2
- LRP1B | c.7480G>C p.D2494H | Missense Mutation (SNP) | VAF 9/98 reads (9%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.819); catalogued as COSV101255972, COSV67203759; called by muse, mutect2
- LRRC8E | c.2165G>A p.R722H | Missense Mutation (SNP) | VAF 20/115 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.005); catalogued as rs190239641; called by muse, mutect2, varscan2
- LRRTM3 | c.901T>G p.W301G | Missense Mutation (SNP) | VAF 29/171 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100791618; called by muse, mutect2, varscan2
- MCAM | c.1023C>G p.N341K | Missense Mutation (SNP) | VAF 16/151 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.186); catalogued as COSV99876154; called by muse, mutect2, varscan2
- MINDY3 | c.722C>T p.S241L | Missense Mutation (SNP) | VAF 6/73 reads (8%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.997); catalogued as COSV99510704; called by muse, mutect2
- MUSK | c.971T>A p.V324E | Missense Mutation (SNP) | VAF 24/123 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.054); catalogued as COSV51898207, COSV99504038; called by muse, mutect2, varscan2
- NEK9 | c.1195G>A p.G399S | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV99463991, COSV99464535; called by muse, mutect2, varscan2
- NHS | c.1405G>A p.G469S | Missense Mutation (SNP) | VAF 8/123 reads (7%) | SIFT tolerated (0.53); PolyPhen probably damaging (0.999); catalogued as COSV101196562; called by muse, mutect2
- NT5C1B | c.386C>A p.S129Y (on ENST00000359846 / NM_001199086.2; = p.S69Y on NM_033253.4) | Missense Mutation (SNP) | VAF 9/106 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.866); catalogued as rs1300398968, COSV100409985; called by muse, mutect2
- OBSCN | c.4189C>T p.R1397* | Nonsense Mutation (SNP) | VAF 21/170 reads (12%) | catalogued as rs1158912574, COSV52746867; called by muse, mutect2, varscan2
- OR10X1 | c.332C>T p.T111I | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as rs772953922, COSV100936642; called by muse, mutect2, varscan2
- OR5D13 | c.320G>T p.C107F | Missense Mutation (SNP) | VAF 44/185 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV62332629; called by muse, mutect2, varscan2
- OR8H1 | c.520C>T p.R174C | Missense Mutation (SNP) | VAF 22/78 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as COSV57293711; called by muse, mutect2, varscan2
- PAPPA2 | c.4097C>T p.S1366L | Missense Mutation (SNP) | VAF 15/87 reads (17%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as rs773829570, COSV62801601; called by muse, mutect2, varscan2
- PCDHB5 | c.1493G>A p.R498H | Missense Mutation (SNP) | VAF 33/253 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.505); catalogued as COSV50648201; called by muse, mutect2, varscan2
- PCDHGA11 | c.995C>T p.T332M | Missense Mutation (SNP) | VAF 14/87 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.327); catalogued as rs1453283842, COSV54037158; called by muse, mutect2, varscan2
- PCDHGA2 | c.395G>T p.R132L | Missense Mutation (SNP) | VAF 6/98 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.017); catalogued as COSV99536809; called by muse, mutect2
- PEX12 | c.301C>G p.Q101E | Missense Mutation (SNP) | VAF 15/373 reads (4%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1316034375, COSV99862129; called by muse, mutect2
- PTPRK | c.2104G>A p.A702T | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT tolerated (0.34); PolyPhen benign (0.108); catalogued as COSV100950900; called by muse, mutect2
- RASSF6 | c.973G>A p.E325K (on ENST00000342081 / NM_201431.2; = p.E293K on NM_177532.5) | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT tolerated (0.14); PolyPhen benign (0.095); catalogued as COSV100274895; called by muse, mutect2
- RPGRIP1L | c.1804C>T p.R602* | Nonsense Mutation (SNP) | VAF 12/57 reads (21%) | catalogued as rs745413543, COSV100046009, COSV50903640; called by muse, mutect2, varscan2
- SLC38A8 | c.448C>T p.R150C | Missense Mutation (SNP) | VAF 18/143 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.36); catalogued as rs141999728; called by muse, mutect2, varscan2
- SLCO6A1 | c.85C>A p.P29T | Missense Mutation (SNP) | VAF 49/258 reads (19%) | SIFT tolerated (0.66); PolyPhen benign (0.007); catalogued as COSV65814898; called by muse, mutect2, varscan2
- SORL1 | c.2444T>C p.L815P | Missense Mutation (SNP) | VAF 14/164 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV99493629; called by muse, mutect2
- SPTA1 | c.3136C>T p.R1046* | Nonsense Mutation (SNP) | VAF 11/134 reads (8%) | catalogued as COSV63751069; called by muse, mutect2
- STAU1 | c.134A>T p.E45V | Missense Mutation (SNP) | VAF 11/228 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.023); catalogued as COSV100574338; called by muse, mutect2
- SYNE1 | c.11846A>G p.D3949G | Missense Mutation (SNP) | VAF 15/90 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.042); catalogued as COSV54936838, COSV99561920; called by muse, mutect2, varscan2
- SYT4 | c.922G>A p.V308I | Missense Mutation (SNP) | VAF 42/127 reads (33%) | SIFT tolerated (0.19); PolyPhen benign (0.108); catalogued as COSV99673711; called by muse, mutect2, varscan2
- TMEM132B | c.2891C>A p.P964Q | Missense Mutation (SNP) | VAF 7/83 reads (8%) | SIFT tolerated (0.48); PolyPhen benign (0.048); catalogued as COSV54751299; called by muse, mutect2
- TPH2 | c.815G>C p.G272A | Missense Mutation (SNP) | VAF 13/141 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100422031; called by muse, mutect2
- TPSAB1 | c.748C>A p.Q250K | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as COSV100127000; called by muse, mutect2, varscan2
- TRPA1 | c.3175G>A p.E1059K | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.448); catalogued as COSV100084001; called by muse, mutect2, varscan2
- TRPS1 | c.2393A>T p.D798V (on ENST00000220888 / NM_001330599.2; = p.D811V on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/478 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.203); catalogued as COSV99630246; called by muse, mutect2
- TRPS1 | c.2392G>T p.D798Y (on ENST00000220888 / NM_001330599.2; = p.D811Y on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 29/484 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.44); catalogued as COSV99630251; called by muse, mutect2
- UNCX | c.418C>A p.L140M | Missense Mutation (SNP) | VAF 15/119 reads (13%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.53); catalogued as COSV100310237; called by muse, mutect2, varscan2
- USP34 | c.4630C>A p.H1544N | Missense Mutation (SNP) | VAF 24/149 reads (16%) | SIFT deleterious (0.05); PolyPhen benign (0.221); catalogued as COSV101276949; called by muse, mutect2, varscan2
- VPS13C | c.6385A>G p.T2129A (on ENST00000644861 / NM_020821.3; = p.T2086A on NM_017684.5) | Missense Mutation (SNP) | VAF 56/267 reads (21%) | SIFT tolerated (0.05); PolyPhen benign (0.041); catalogued as COSV99828274; called by muse, mutect2, varscan2
- XPO7 | c.1485G>A p.W495* | Nonsense Mutation (SNP) | VAF 7/185 reads (4%) | catalogued as COSV99381155; called by muse, mutect2
- ZNF462 | c.3679C>T p.R1227W | Missense Mutation (SNP) | VAF 17/429 reads (4%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs1365581456, COSV52945559; called by muse, mutect2
- ZNF548 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 22/112 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV100278086; called by muse, mutect2, varscan2
- ZNF548 | c.4A>C p.N2H | Missense Mutation (SNP) | VAF 21/112 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.029); catalogued as COSV100278089; called by muse, mutect2, varscan2
- ARID1A | c.5419_5420del p.S1807* | Frame Shift Del (DEL) | VAF 21/73 reads (29%) | called by mutect2, pindel, varscan2
- C2CD6 | c.1706C>G p.S569C | Missense Mutation (SNP) | VAF 15/521 reads (3%) | SIFT tolerated (0.12); PolyPhen benign (0.012); called by muse, mutect2
- AXL | c.1911C>G p.L637= (on ENST00000301178 / NM_021913.5; = p.L628= on NM_001699.6) | Silent (SNP) | VAF 13/130 reads (10%) | catalogued as rs771768158, COSV99996458; called by muse, mutect2
- BIRC6 | c.11712G>A p.A3904= | Silent (SNP) | VAF 6/13 reads (46%) | catalogued as rs373938876; called by muse, varscan2
- CLIP2 | c.699C>T p.G233= | Silent (SNP) | VAF 18/213 reads (8%) | catalogued as rs925703428, COSV99791485; called by muse, mutect2
- HTR3E | c.921C>G p.L307= (on ENST00000415389 / NM_001256613.1; = p.L322= on NM_182589.2) | Silent (SNP) | VAF 8/190 reads (4%) | catalogued as COSV100093981; called by muse, mutect2
- IGHV4-39 | c.198C>G p.R66= | Silent (SNP) | VAF 20/124 reads (16%) | catalogued as rs34195693; called by muse, mutect2, varscan2
- INSL5 | c.48C>A p.A16= | Silent (SNP) | VAF 4/47 reads (9%) | catalogued as COSV100455402; called by muse, mutect2
- MEF2D | c.819C>T p.I273= | Silent (SNP) | VAF 24/131 reads (18%) | catalogued as COSV100560009, COSV61727442; called by muse, mutect2, varscan2
- MUC16 | c.14046G>A p.Q4682= | Silent (SNP) | VAF 17/156 reads (11%) | catalogued as COSV67442772; called by muse, mutect2, varscan2
- NFE2L1 | c.645C>T p.T215= | Silent (SNP) | VAF 82/232 reads (35%) | catalogued as COSV100671520; called by muse, mutect2, varscan2
- SLC47A1 | c.711G>A p.G237= | Silent (SNP) | VAF 34/111 reads (31%) | catalogued as COSV54501198; called by muse, mutect2, varscan2
- TRMT6 | c.99G>A p.V33= | Silent (SNP) | VAF 17/178 reads (10%) | catalogued as COSV99177561; called by muse, mutect2, varscan2
- TRPC3 | c.654C>T p.D218= (on ENST00000379645 / NM_001366479.2; = p.D145= on NM_003305.2) | Silent (SNP) | VAF 11/46 reads (24%) | catalogued as rs766293867, COSV53374224; called by muse, mutect2, varscan2
